Somatic mutation profile of tumor specimen HCM-BROD-0045-C16-06A (aliquot HCM-BROD-0045-C16-06A-01D-A79C-36) from HCMI case HCM-BROD-0045-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.1 years (21,217 days).
Specimen HCM-BROD-0045-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a21e9d8-c682-4dc6-b16a-81b8eeb25962.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0045-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0045-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e3af57e-2fc8-403d-9d3e-1f70c68c9888

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 2, Intron 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF6B | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 17/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372088619; called by muse, mutect2
- AXIN1 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 25/515 reads (5%) | catalogued as COSV51982971; called by muse, mutect2
- C7orf26 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100732973; called by muse, mutect2
- NUCB1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs773762425; called by muse, mutect2
- REG3G | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 13/427 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV55449177; called by muse, mutect2
- STAB2 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 19/495 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV66343716; called by muse, mutect2
- ARHGAP27 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 26/1032 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- BSN | c.9016G>A p.G3006S | Missense Mutation (SNP) | VAF 26/808 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.116); called by muse, mutect2
- FAHD2A | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 20/520 reads (4%) | called by muse, mutect2
- KCNA5 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 27/920 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2
- OR11H7 | c.495A>C p.Q165H | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2
- PACS1 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 36/479 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- PPP4R3C | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TSSK6 | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 20/619 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); called by muse, mutect2
- UBA5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2
- ECEL1 | c.75G>A p.A25= | Silent (SNP) | VAF 39/928 reads (4%) | catalogued as rs985763887, COSV58811218; called by muse, mutect2
- HERC1 | c.8424C>T p.S2808= | Silent (SNP) | VAF 17/561 reads (3%) | catalogued as rs1179061887; called by muse, mutect2
- MTMR4 | c.109C>T p.L37= | Silent (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
- MUC12 | c.234G>A p.E78= | Silent (SNP) | VAF 17/609 reads (3%) | catalogued as rs1433563406; called by muse, mutect2
- MYO19 | c.1239G>A p.L413= | Silent (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
- NEU2 | c.747C>T p.T249= | Silent (SNP) | VAF 26/800 reads (3%) | called by muse, mutect2
- CNKSR2 | c.2693-7295A>G | Intron (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- KCNQ2 | c.*5864G>A | 3'UTR (SNP) | VAF 26/1044 reads (2%) | called by muse, mutect2
- MAMLD1 | c.*2C>A | 3'UTR (SNP) | VAF 15/242 reads (6%) | catalogued as rs368568633, COSV53373626; called by muse, mutect2
- ST7 | c.865+35C>T | Intron (SNP) | VAF 231/579 reads (40%) | called by muse, mutect2, varscan2
